Gene-level copy-number profile of tumor specimen TCGA-D3-A2JE-06A from TCGA case TCGA-D3-A2JE, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 76.0 years (27,744 days).
Specimen TCGA-D3-A2JE-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.9fef0e9f-e327-4c7a-b126-e6135c45b138.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A2JE-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3946051b-18a5-4a9f-8593-da14a2d97034

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 7; copy number 2: 2,629; copy number 3: 27,113; copy number 4: 17,472; copy number 5: 7,942; copy number 6: 408; copy number 7: 2,027; copy number 8: 775; copy number 9: 1,254; copy number 10: 128; copy number 36: 58.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A2JE-06A-11D-A371-01): tumor purity 0.79, ploidy 3.68, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,850,277–116,965,227, 4 genes: MIR4447, AC069504.1, LINC00901, RNU5E-8P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,155 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:78,148,101–145,066,685, 1,061 genes, copy number 7–10 (broad region; genes not listed).
- chr18:47,390–8,974,580, 173 genes, copy number 7 (broad region; genes not listed).
- chr18:20,946,906–80,247,514, 863 genes, copy number 8–9 (broad region; genes not listed).
- chr19:6,661,253–7,864,976, 58 genes, copy number 36 (within-gene range 5–36): TNFSF14, C3, AC008760.2, GPR108, MIR6791, TRIP10, AC008760.1, SH2D3A, VAV1, ADGRE1, AC020895.2, AC020895.1, Metazoa_SRP, ADGRE4P, AC025278.1, AC025278.2, AC025278.3, MBD3L2B, MBD3L5, MBD3L4, MBD3L2, MBD3L3, ZNF557, INSR, AC119396.1, AC008878.3, AC119396.2, ARHGEF18, PEX11G, TEX45, AC008878.1, ZNF358, AC008878.4, MCOLN1, AC008878.2, PNPLA6, CAMSAP3, MIR6792, XAB2, PET100, AC008763.2, PCP2, AC008763.1, STXBP2, RPS27AP19, RETN, MCEMP1, AC008763.3, TRAPPC5, FCER2, CLEC4G, AC008763.4, CD209, RPL21P129, CLEC4M, CLEC4GP1, EXOSC3P2, EVI5L.

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
